Gene-level copy-number profile of tumor specimen TCGA-HU-A4H4-01A from TCGA case TCGA-HU-A4H4, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 53.8 years (19,665 days).
Specimen TCGA-HU-A4H4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.f4dcfc1a-3bf6-46d3-a42a-1cc9468677dd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4H4-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/913c1645-53ce-43a3-8ca6-54b9fb16d899

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 3,049; copy number 2: 34,574; copy number 3: 15,385; copy number 4: 5,199; copy number 5: 1,513; copy number 6: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4H4-01A-21D-A253-01): tumor purity 0.37, ploidy 2.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,723,713–22,499,749, 91 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,521 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:146,909,685–198,222,513, 915 genes, copy number 5 (broad region; genes not listed).
- chr4:162,322,188–163,520,539, 14 genes, copy number 5: MTHFD2P4, TOMM22P4, AC021134.1, AC021134.2, AC084752.1, MIR4454, AC022272.1, NAF1, AC079238.1, NPY1R, NPY5R, RPL35AP12, TKTL2, TMA16.
- chr4:163,529,771–163,530,697, 1 gene, copy number 5: AC093788.1.
- chr6:79,854,684–80,042,527, 8 genes, copy number 6: AL132875.1, AL132875.3, AL132875.2, ELOVL4, AL133475.1, GAPDHP63, RPL35AP18, TTK.
- chr11:123,188,802–123,655,244, 8 genes, copy number 5 (within-gene range 3–5): AP001970.1, U8, LINC02727, PHBP17, GRAMD1B, MIR4493, SF3A3P2, SCN3B.
- chr18:21,529,284–23,026,488, 40 genes, copy number 5 (within-gene range 2–5): ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P.
- chr20:87,250–26,114,028, 535 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,805. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
